Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0U3, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0U3-01A (Primary Tumor).

ICD-0-3

carcinoma infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9

Breast, left, wide-local excision: Invasive ductal adenocarcinoma, Nottingham grade III (of III), forming a mass 2.3 x 2.0 x 2.0 cm (AJCC pT2). Ductal carcinoma in-situ, high nuclear grade, solid type comprises 10% of the tumor. The surgical margins are negative for tumor.

Lymph nodes, left axillary sentinel, excision: A single (1) left axillary sentinel lymph node is positive for tumor (AJCC pN1mi). No blue dye identified.

Lymph nodes, left axillary, excision: Multiple (3) left axillary lymph nodes are negative for tumor (AJCC pN0).

Estrogen: Positive, > 10% nuclear staining

Progesterone: Focally Positive, 1-10% nuclear staining

ER (Estrogen Receptor) test was developed and its performance characteristics determined by . It has not been cleared or approved by the U.S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 8103e287-5093-40de-9b02-a99e4f41b44f (TCGA-AR-A0U3.ED2D1BA8-8FEB-43E1-9174-91F9D59565F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).